Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3322, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3322-01A (Primary Tumor).

[page 1 of 2]
Laboratory Patient Report
Print Date/Time: [REDACTED]

Surgical Pathology

Histopathological Examination

Path#: [REDACTED]
Collected: [REDACTED] Received: [REDACTED] Complete [REDACTED]

Pre-Op Diagnosis : Lt Renal Mass
Order Physician [REDACTED]
Specimens : Kidney, Left
Frozen Diagnosis :

Report

: GROSS EXAMINATION.

The specimen is received in a container labeled with the name of the patient and labeled as kidney, left. The specimen consists of a nephrectomy specimen including perinephric fat and Gerota's fascia that measures en bloc 16 x 10 x 5.5 cm and weighs 465 g. The 9.7 x 5.6 x 4cm kidney weighs 130 g. Near the inferior pole is a posterior 3 x 2.8 x 2cm, circumscribed, tumor nodule. The capsule is easily removed. The overlying fat at the tumor nodule is labeled with blue dye. The cortex has an average thickness of 0.6 cm. The renal pyramids are blunted. The calyces are narrowed. The pelvis is grossly unremarkable. The 5.7 cm long, ureter has an average diameter of 0.3 cm. Sections are submitted in seven blocks as follows: 1-renal tumor; 5-overlying capsule and fat; 6-uninvolved kidney; 7-ureter, renal vessels. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

SPECIMEN TYPE: Radical nephrectomy

LATERALITY: Left

TUMOR SITE: Lower pole

FOCALITY: Unifocal

TUMOR SIZE (LARGEST TUMOR IF MULTIPLE):

Greatest dimension: 3.0 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): Grade 2

EXTENT OF INVASION

PRIMARY TUMOR (PT): pTa: Tumor 4 cm or less in greatest dimension, limited to the kidney

REGIONAL LYMPH NODES (PN): pNX: Cannot be assessed

DISTANT METASTASIS (PM): pMX: Cannot be assessed

MARGINS: Margins uninvolved by invasive carcinoma

[page 2 of 2]
ADRENAL GLAND: Not present
VENOUS (LARGE VESSEL) INVASION (V): Absent
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent
ADDITIONAL PATHOLOGIC FINDINGS: None identified.
Intradepartmental consultation obtained.
[T-71000 M-83103 189.0 P3-44070]

[REDACTED] Pathology

Electronically Signed by:
[REDACTED]

Source: NCI Genomic Data Commons file de48969d-0d2e-4e46-ad99-29fa51a0b6e0 (TCGA-A3-3322.827E3E8A-470F-4B5D-9DCA-75D1C7F07FD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).